Gene-level copy-number profile of tumor specimen TCGA-DX-AB2P-01A from TCGA case TCGA-DX-AB2P, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 79.8 years (29,136 days).
Specimen TCGA-DX-AB2P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d8c7fd5f-d353-4ecf-8cc5-881056c38275.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41fc5d19-c731-43d7-bc92-738405fd338a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 499; copy number 2: 8,449; copy number 3: 20,537; copy number 4: 15,837; copy number 5: 8,302; copy number 6: 5,198; copy number 7: 349; copy number 8: 584.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2P-01A-11D-A386-01): tumor purity 0.84, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–50,125,720, 51 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,361,763, 6 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 933 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,230,030–13,825,079, 58 genes, copy number 7: VPS13D, SNORA59A, LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1, AADACL3, C1orf158, PRAMEF12, PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:14,124,233–14,304,445, 2 genes, copy number 7: RNU6-1265P, AL357873.1.
- chr4:49,096–2,732,573, 95 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:143,184,917–156,006,988, 226 genes, copy number 7–8 (broad region; genes not listed).
- chr5:16,661,907–29,796,268, 156 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:51,615,299–53,153,898, 40 genes, copy number 7 (within-gene range 4–7): PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P.
- chr8:67,422,038–67,849,338, 4 genes, copy number 7 (within-gene range 4–7): CPA6, NACAP10, AC022874.1, NDUFS5P6.
- chr13:95,801,580–96,053,482, 1 gene, copy number 7 (within-gene range 5–7): UGGT2.
- chr13:96,090,839–97,476,459, 18 genes, copy number 7: HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4.
- chr17:13,299,184–16,218,185, 77 genes, copy number 8 (broad region; genes not listed).
- chr17:17,843,511–17,972,422, 1 gene, copy number 8 (within-gene range 5–8): TOM1L2.
- chr17:17,972,813–27,003,259, 255 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 499. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
